Gene-level copy-number profile of tumor specimen C3L-02858-01 from CPTAC case C3L-02858, project CPTAC-3 (Kidney — Lipomatous Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angiomyolipoma; Tissue or organ of origin: Kidney, NOS; Tumor grade: GX; Age at diagnosis: 39.8 years (14,545 days).
Specimen C3L-02858-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c3dbdf1d-445f-4594-a4d7-7bfd77e2cba0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02858-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/a1cc0d46-3422-4e7f-9363-142c95329a7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19; copy number 2: 58,384.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
